Somatic mutation profile of tumor specimen TCGA-CW-6097-01A (aliquot TCGA-CW-6097-01A-11D-1669-08) from TCGA case TCGA-CW-6097, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 32.0 years (11,701 days).
Specimen TCGA-CW-6097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a919da25-5c12-46db-acb3-0655ec104ed5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-6097-11A (Solid Tissue Normal), aliquot TCGA-CW-6097-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28abf04e-6ddc-4ee5-baff-7d7052e331df

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST2 | c.631T>G p.S211A | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as rs1488763839, COSV58885225; called by muse, mutect2
- CMTR2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs769589947, COSV57602643; called by muse, mutect2, varscan2
- EEF1A1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV58549303; called by muse, mutect2
- ELMO3 | c.2200A>T p.M734L (on ENST00000652269; = p.M681L on NM_024712.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV58526992; called by muse, mutect2
- GPNMB | c.1633C>T p.L545F (on ENST00000381990 / NM_001005340.2; = p.L533F on NM_002510.3) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV51697778; called by muse, mutect2
- GPR17 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754384501, COSV55753796; called by muse, mutect2
- HELZ2 | c.5869G>A p.A1957T (on ENST00000467148 / NM_001037335.2; = p.A1388T on NM_033405.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs530022156, COSV71295705; called by muse, varscan2
- MYH8 | c.5024C>T p.A1675V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1322113245, COSV67963038; called by muse, mutect2, varscan2
- OR8G1 | c.672C>G p.S224R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); catalogued as COSV100422240, COSV100422245; called by muse, mutect2, varscan2
- OR8K1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV54402059, COSV99687339; called by muse, mutect2, varscan2
- POTEF | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as rs201025840, COSV62540666; called by muse, mutect2
- SEPTIN2 | c.554A>C p.D185A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63472022; called by muse, mutect2
- SNTG1 | c.933G>T p.R311S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV52435991, COSV52459354; called by muse, mutect2
- TAC1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs772094189, COSV59987225; called by muse, mutect2, varscan2
- TMEM190 | c.485A>G p.E162G | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.986); catalogued as COSV52581576; called by muse, mutect2, varscan2
- BAP1 | c.1628_1631del p.C543Yfs*27 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- U2AF2 | c.1296del p.F433Lfs*17 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel, varscan2
- OR2T6 | c.399T>C p.P133= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as rs755546757, COSV63216042; called by muse, mutect2
- OR6C75 | c.789A>G p.R263= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs1297619020, COSV58551835; called by muse, mutect2, varscan2
- TICAM1 | c.1884G>T p.P628= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs773993340, COSV50229775, COSV99941000; called by muse, mutect2, varscan2
- TRO | c.2301C>T p.A767= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV51500049, COSV51506586; called by muse, mutect2, varscan2
- VWF | c.2025G>A p.P675= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs779045480, COSV54616505, COSV54627481; ClinVar: uncertain significance; called by muse, mutect2
- CDC5L | c.*2del | 3'UTR (DEL) | VAF 7/65 reads (11%) | called by mutect2, varscan2
